Somatic mutation profile of tumor specimen TCGA-HD-A4C1-01A (aliquot TCGA-HD-A4C1-01A-11D-A24D-08) from TCGA case TCGA-HD-A4C1, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 41.3 years (15,096 days).
Specimen TCGA-HD-A4C1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ae570ee-2109-4dc2-8c71-1c90f9eb47a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-A4C1-10A (Blood Derived Normal), aliquot TCGA-HD-A4C1-10A-02D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e17c387-2862-43d7-b9bb-fc3f0a234ac1

The open-access MAF lists 207 somatic variants for this specimen: 149 protein-altering or splice-affecting, 55 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 55, Nonsense Mutation 9, Splice Site 4, Frame Shift Del 4, Intron 3, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs104894230, CM053284, CM081305, CM123157, COSV54236734, COSV54236774, COSV54238174; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.1705G>A p.G569R | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as COSV99900010; called by muse, mutect2, varscan2
- ADRA2B | c.34A>T p.T12S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV101337385; called by muse, mutect2, varscan2
- ALPK2 | c.5450C>G p.S1817C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100864717; called by muse, mutect2, varscan2
- ANKRD50 | c.3865A>T p.S1289C | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.157); catalogued as COSV101539017; called by muse, mutect2, varscan2
- ANKRD50 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs948452945, COSV101539018; called by muse, mutect2, varscan2
- ARFGEF2 | c.1891C>T p.Q631* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100904414; called by muse, mutect2, varscan2
- ARHGEF1 | c.1268-1G>C p.X423_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100529151; called by muse, mutect2, varscan2
- ARHGEF1 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV100529153; called by muse, mutect2, varscan2
- ARHGEF5 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99283101; called by muse, mutect2, varscan2
- ARSD | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66973320; called by muse, mutect2, varscan2
- ATP13A5 | c.2671C>T p.L891F | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs150829984; called by muse, mutect2, varscan2
- ATP1A1 | c.2881G>C p.E961Q | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.595); catalogued as COSV99814682; called by muse, mutect2, varscan2
- ATP2B1 | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV99666026; called by muse, mutect2, varscan2
- ATRX | c.1152T>A p.S384R | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV100971264; called by muse, mutect2, varscan2
- BCKDHB | c.844C>G p.H282D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100243936; called by muse, mutect2, varscan2
- BRWD3 | c.4339C>T p.R1447W | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs764350439, COSV100956384; called by muse, mutect2, varscan2
- C6orf136 | c.530A>G p.E177G (on ENST00000376473 / NM_001109938.3; = p.E43G on NM_145029.4) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV99528148; called by muse, mutect2
- CACNA1H | c.4465A>C p.N1489H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100673324; called by muse, mutect2, varscan2
- CASP8 | c.550+2T>C p.X184_splice (on ENST00000432109 / NM_033355.3; = p.X216_splice on NM_001228.4) | Splice Site (SNP) | VAF 30/81 reads (37%) | catalogued as rs756660014, COSV51848988, COSV99965763; called by muse, mutect2, varscan2
- CASP8 | c.1237C>T p.R413* (on ENST00000432109 / NM_033355.3; = p.R430* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as rs1272714323, COSV51845663; called by muse, mutect2, varscan2
- CCDC110 | c.1894C>G p.Q632E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV100294117; called by muse, mutect2, varscan2
- CCDC110 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs376940059; called by muse, mutect2, varscan2
- CENPF | c.6094C>T p.H2032Y | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as COSV100871890, COSV100871928; called by muse, mutect2
- CHRNA6 | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV99373348; called by muse, mutect2, varscan2
- CNTROB | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs376598201; called by muse, varscan2
- COL28A1 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.435); catalogued as COSV101258862, COSV68085576; called by muse, mutect2
- COL5A1 | c.1154A>G p.N385S | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV100880386; called by muse, mutect2, varscan2
- COL9A2 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs755487302, COSV65623903; called by muse, mutect2
- CREB5 | c.1319A>G p.D440G (on ENST00000357727 / NM_182898.4; = p.D433G on NM_004904.3) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100745264; called by muse, mutect2, varscan2
- CTNNA2 | c.1861C>T p.R621W | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as COSV58139677; called by muse, mutect2, varscan2
- CTNND1 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.703); catalogued as COSV62383707; called by muse, mutect2, varscan2
- DCTN1 | c.445C>G p.R149G | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.931); catalogued as COSV100721032, COSV62619893; called by muse, mutect2, varscan2
- DDX60 | c.4820A>G p.N1607S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV101190590; called by muse, mutect2, varscan2
- DEAF1 | c.372C>G p.I124M | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV100102274; called by muse, mutect2, varscan2
- DLC1 | c.1575T>A p.D525E (on ENST00000276297 / NM_001348081.2; = p.D88E on NM_006094.5) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99364826; called by muse, mutect2, varscan2
- DMD | c.1158G>A p.M386I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99925025; called by muse, mutect2, varscan2
- DNAH2 | c.8989C>T p.R2997W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs757065362, COSV101209536; called by muse, mutect2, varscan2
- EDRF1 | c.1445G>C p.R482T (on ENST00000356792 / NM_001202438.2; = p.R448T on NM_015608.2) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100523821; called by muse, mutect2, varscan2
- EGFLAM | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.106); catalogued as COSV100472916, COSV59310252; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423565989, COSV57518028; called by muse, mutect2, varscan2
- EPB42 | c.24G>C p.K8N (on ENST00000441366 / NM_001114134.2; = p.K38N on NM_000119.3) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV100282096, COSV55750236; called by muse, mutect2, varscan2
- F5 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.535); catalogued as rs370383592, COSV63127538; called by muse, mutect2, varscan2
- FAM53B | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.349); catalogued as COSV100484214; called by muse, mutect2, varscan2
- FAM8A1 | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99467893; called by muse, mutect2, varscan2
- FANCD2OS | c.99C>G p.F33L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.08); catalogued as COSV101090988, COSV101091762; called by muse, mutect2, varscan2
- FAT1 | c.3599C>G p.S1200* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV101499573; called by muse, mutect2, varscan2
- FBXO34 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs535237309, COSV58254210, COSV58255842; called by muse, mutect2, varscan2
- FBXW11 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.372); catalogued as COSV99441264; called by muse, mutect2, varscan2
- FGD1 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.714); catalogued as COSV100911227, COSV64308585; called by muse, mutect2, varscan2
- FLNC | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.23); catalogued as rs371410741; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATM | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761575775, COSV67540612; called by muse, mutect2, varscan2
- GBP5 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.243); catalogued as COSV100600147; called by muse, mutect2, varscan2
- GLDC | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as CD1510129, COSV100394449; called by muse, mutect2, varscan2
- GREB1 | c.5840G>A p.R1947Q | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as rs772872339, COSV99303527; called by muse, mutect2, varscan2
- GRIN2B | c.1771G>T p.D591Y | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV101663144, COSV74205966; called by muse, mutect2, varscan2
- GRM1 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51112256; called by muse, mutect2, varscan2
- H1-4 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV99175338; called by muse, mutect2, varscan2
- HLA-B | c.748C>G p.Q250E | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV69522776, COSV69523296; called by muse, mutect2, varscan2
- HNRNPR | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV100164676; called by muse, mutect2, varscan2
- HSPG2 | c.6131C>G p.S2044* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV101021042; called by muse, mutect2, varscan2
- HYAL4 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as rs775696490, COSV99772403; called by muse, mutect2, varscan2
- IFNAR2 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.661); catalogued as rs778792208, COSV59746370; called by muse, mutect2, varscan2
- IL13RA2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.054); catalogued as COSV99683294; called by muse, mutect2, varscan2
- IL5RA | c.780A>T p.K260N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99843210; called by muse, mutect2, varscan2
- IMP3 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100145873; called by muse, mutect2, varscan2
- IRS1 | c.1493C>T p.T498I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV59335968; called by muse, mutect2, varscan2
- JHY | c.405G>C p.K135N | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.077); catalogued as COSV99913594; called by muse, mutect2, varscan2
- KIF21B | c.2836-1G>A p.X946_splice | Splice Site (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100144773; called by muse, mutect2
- KLHDC4 | c.504C>T p.V168= | Splice Region (SNP) | VAF 41/163 reads (25%) | catalogued as rs768690332, COSV99566640; called by muse, mutect2, varscan2
- KPNA2 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 97/329 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs782797109, COSV100388857; called by muse, mutect2, varscan2
- LRRC7 | c.2459A>C p.E820A (on ENST00000651989 / NM_001370785.2; = p.E787A on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV99228927; called by muse, mutect2, varscan2
- LRRN3 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100072591; called by muse, mutect2, varscan2
- LRRTM3 | c.1588A>G p.I530V | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as rs781343554, COSV100791858; called by muse, mutect2, varscan2
- MAGEA3 | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100939073; called by muse, mutect2, varscan2
- MB21D2 | c.1112A>G p.N371S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV101165152; called by muse, mutect2, varscan2
- MED1 | c.4673C>T p.S1558L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.374); catalogued as COSV100327435, COSV100328071; called by muse, mutect2, varscan2
- MGAT5B | c.1141T>G p.S381A | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.876); catalogued as COSV100048730; called by muse, mutect2, varscan2
- MIXL1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs745392060, COSV100830830; called by muse, mutect2, varscan2
- MLLT1 | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV99398204; called by muse, varscan2
- MMP2 | c.530A>G p.E177G | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99528146; called by muse, mutect2, varscan2
- MYO5B | c.4492C>T p.P1498S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV99546005; called by muse, mutect2, varscan2
- NLRP13 | c.1927C>A p.H643N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV100738418; called by muse, mutect2
- NME1-NME2 | c.683G>A p.R228Q (on ENST00000555572; = p.R203Q on NM_001018136.3) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs777392074, COSV64510524; called by muse, mutect2, varscan2
- NUP214 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV63912682; called by muse, mutect2, varscan2
- ODAM | c.120A>T p.Q40H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV101258101; called by muse, mutect2, varscan2
- PAN2 | c.2689C>T p.L897F (on ENST00000425394 / NM_001127460.3; = p.L893F on NM_014871.5) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as COSV99228223, COSV99228439; called by muse, mutect2, varscan2
- PAN2 | c.2585C>T p.S862L (on ENST00000425394 / NM_001127460.3; = p.S858L on NM_014871.5) | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV99228441; called by muse, mutect2, varscan2
- PCDH15 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV100225740; called by muse, mutect2, varscan2
- PCDHA5 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100972483; called by muse, mutect2, varscan2
- PCK2 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 42/171 reads (25%) | catalogued as rs373164648; called by muse, mutect2, varscan2
- PCNX1 | c.4016G>A p.R1339Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs201817854, COSV53092154; called by muse, mutect2, varscan2
- PDK3 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.099); catalogued as COSV100998195; called by muse, mutect2
- PKNOX2 | c.1184A>T p.N395I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.133); catalogued as COSV100021634; called by muse, mutect2, varscan2
- PLEKHA5 | c.1361A>G p.Y454C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as rs142101396; called by muse, mutect2, varscan2
- PLXNA3 | c.3248G>A p.G1083D | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV100860182; called by muse, mutect2, varscan2
- POLK | c.2249C>T p.S750L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV99606318; called by muse, mutect2, varscan2
- POLR2L | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 83/156 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV100431877; called by muse, mutect2, varscan2
- PRKACB | c.645C>A p.G215= | Splice Region (SNP) | VAF 19/95 reads (20%) | catalogued as COSV100853986; called by muse, mutect2, varscan2
- PRRC2A | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as rs201317702; called by muse, mutect2, varscan2
- PTPN4 | c.246+2T>G p.X82_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99751078; called by muse, varscan2
- RBMXL1 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.891); catalogued as COSV99556822; called by muse, mutect2, varscan2
- RECQL5 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.442); catalogued as COSV100512242; called by muse, mutect2, varscan2
- RNF103 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.08); catalogued as COSV99410343; called by muse, mutect2, varscan2
- RNF32 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV100311564; called by muse, mutect2
- RRAD | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV55337225; called by muse, mutect2, varscan2
- RYR1 | c.5464G>A p.G1822S | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.588); catalogued as rs1169294876, COSV100614822, COSV62113655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.9365G>A p.R3122Q (on ENST00000389232; = p.R3123Q on NM_001036.6) | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs777690183, COSV66778248; called by muse, mutect2, varscan2
- SEMA6B | c.1520C>T p.S507L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.903); catalogued as rs769521225, COSV100015055; called by muse, mutect2, varscan2
- SH2D3A | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 193/325 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs759149797, COSV55585751; called by muse, mutect2, varscan2
- SLAIN1 | c.1142A>T p.Y381F (on ENST00000466548; = p.Y118F on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1369211069, COSV99935398; called by muse, mutect2, varscan2
- SLC18B1 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs368128212; called by muse, mutect2, varscan2
- SLC24A2 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.23); catalogued as COSV99646209, COSV99647205; called by muse, mutect2, varscan2
- SLC2A13 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as rs1441961214, COSV99786921; called by muse, mutect2, varscan2
- SLC35A5 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV99656893; called by muse, mutect2, varscan2
- SLC44A4 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.819); catalogued as rs368786095, COSV99999198; called by muse, mutect2, varscan2
- SLCO1B3 | c.688T>C p.F230L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.034); catalogued as COSV99682046; called by muse, mutect2
- SLFN11 | c.1778G>A p.R593K | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as COSV100390902; called by muse, mutect2
- SMG7 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100750508; called by muse, mutect2, varscan2
- SNF8 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.099); catalogued as COSV99287803; called by muse, mutect2
- SOCS5 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100125420; called by muse, mutect2, varscan2
- SPTAN1 | c.6391G>A p.E2131K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.049); catalogued as rs755273355, COSV100823604; called by muse, mutect2, varscan2
- SRP68 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100326229; called by muse, varscan2
- STAB2 | c.3886G>A p.G1296R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV101185602, COSV101186221; called by muse, mutect2, varscan2
- STAG2 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV54356717, COSV54365939, COSV54376336; called by muse, mutect2, varscan2
- TAAR9 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV71512343; called by muse, mutect2, varscan2
- TBCD | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as rs1428485417, COSV100833626; called by muse, mutect2
- TLR8 | c.1882G>T p.D628Y (on ENST00000218032 / NM_138636.5; = p.D646Y on NM_016610.4) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99487211; called by muse, mutect2, varscan2
- TMEM132A | c.2539G>C p.E847Q (on ENST00000453848 / NM_178031.3; = p.E848Q on NM_017870.4) | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs766430879, COSV99136768; called by muse, mutect2, varscan2
- TRIOBP | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV100731051; called by muse, mutect2, varscan2
- TUBB | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.384); catalogued as COSV100013446; called by muse, mutect2, varscan2
- UBE3C | c.1921C>G p.Q641E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV100780043; called by muse, mutect2, varscan2
- USP34 | c.8860G>C p.E2954Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV101277154; called by muse, mutect2, varscan2
- WFS1 | c.1286G>T p.C429F | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99901517; called by muse, mutect2, varscan2
- WNK3 | c.3262C>G p.Q1088E | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV100671941; called by muse, mutect2, varscan2
- ZFP69 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs548547006, COSV65528533; called by muse, mutect2, varscan2
- ZHX3 | c.2622G>A p.M874I | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as COSV100476539; called by muse, mutect2, varscan2
- ZMAT2 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV99218158; called by muse, mutect2, varscan2
- ZNF281 | c.2056C>T p.L686F | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99664467; called by muse, mutect2, varscan2
- ZNF341 | c.2512G>A p.E838K (on ENST00000375200 / NM_001282935.1; = p.E831K on NM_032819.4) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.053); catalogued as rs780567337, COSV61006396; called by muse, mutect2, varscan2
- ZNF425 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV65201200; called by muse, mutect2, varscan2
- ZNF582 | c.458A>G p.D153G | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100018870; called by muse, mutect2, varscan2
- ZNF676 | c.1777T>A p.Y593N (on ENST00000650058; = p.Y561N on NM_001001411.3) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV101236299; called by muse, mutect2, varscan2
- ZSCAN22 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV100308458; called by muse, mutect2, varscan2
- DST | c.19137_19152del p.G6381Lfs*8 (on ENST00000361203 / NM_001374722.1; = p.G4078Lfs*8 on NM_015548.5) | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel
- FAT1 | c.4659_4660del p.S1553Rfs*4 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- FOSL1 | c.630del p.E211Nfs*11 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- HLA-A | c.133dup p.R45Pfs*54 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- PAN2 | c.2434_2435del p.S812Hfs*18 (on ENST00000425394 / NM_001127460.3; = p.S808Hfs*18 on NM_014871.5) | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | called by pindel, varscan2
- ABCA13 | c.8412T>C p.S2804= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs767031271, COSV101447142; called by mutect2, varscan2
- ABCD4 | c.852G>C p.L284= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs1337872562, COSV100084475; called by muse, mutect2, varscan2
- ABCG4 | c.123G>A p.E41= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100266955; called by muse, mutect2, varscan2
- AHNAK | c.10551C>T p.L3517= | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as rs201491068; called by muse, mutect2, varscan2
- AKAP12 | c.360C>T p.S120= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs777029366, COSV53577973; called by muse, mutect2
- ANOS1 | c.1101C>T p.D367= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs765962654, COSV99391281; called by muse, mutect2, varscan2
- AP4M1 | c.336C>G p.L112= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100385109; called by muse, varscan2
- ATMIN | c.540G>A p.L180= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as COSV100214742; called by muse, mutect2, varscan2
- ATP10A | c.2664C>T p.L888= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as COSV100791430; called by muse, mutect2, varscan2
- ATRX | c.1824T>A p.V608= | Silent (SNP) | VAF 97/290 reads (33%) | catalogued as COSV100971263; called by muse, mutect2, varscan2
- BARD1 | c.462C>T p.V154= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99639560; called by muse, mutect2, varscan2
- C2orf42 | c.363G>C p.L121= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100034116; called by muse, mutect2, varscan2
- CACNA1D | c.5475G>T p.R1825= (on ENST00000350061 / NM_001128840.3; = p.R1845= on NM_000720.4) | Silent (SNP) | VAF 35/149 reads (23%) | catalogued as COSV99859525; called by muse, mutect2, varscan2
- CACNG4 | c.762C>G p.P254= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100047817; called by muse, mutect2, varscan2
- CADM1 | c.759A>G p.L253= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs530669537, COSV100523203; called by muse, mutect2, varscan2
- CCDC150 | c.1689A>G p.K563= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99777282; called by muse, mutect2
- CCSER1 | c.1080G>A p.V360= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs761424550, COSV100395115; called by muse, mutect2, varscan2
- CD40LG | c.642C>T p.S214= | Silent (SNP) | VAF 87/319 reads (27%) | catalogued as rs761216947, COSV65698321; called by muse, mutect2, varscan2
- CHRD | c.1056C>G p.V352= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99200672; called by muse, mutect2, varscan2
- ESYT1 | c.789C>T p.F263= | Silent (SNP) | VAF 52/158 reads (33%) | catalogued as rs1344902984, COSV99920206; called by muse, mutect2, varscan2
- EWSR1 | c.615G>A p.Q205= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV100131976; called by muse, mutect2, varscan2
- FAM199X | c.168C>G p.T56= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1556374124, COSV101534172; called by muse, mutect2, varscan2
- FANCA | c.2184G>A p.Q728= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV101225120; called by muse, mutect2, varscan2
- GLDC | c.645G>A p.K215= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV100394450; called by muse, mutect2, varscan2
- GLP2R | c.1458C>T p.G486= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs139614327; called by muse, mutect2, varscan2
- HGSNAT | c.1905C>T p.I635= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99925440; called by muse, mutect2
- HSPA12B | c.549C>T p.H183= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV99654171; called by muse, mutect2, varscan2
- IRF3 | c.708G>A p.R236= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs375866058, COSV99881266; called by muse, mutect2, varscan2
- IRF3 | c.618G>A p.V206= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99880907; called by muse, varscan2
- KCNG2 | c.1332G>A p.S444= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs752211575, COSV100302028; called by muse, mutect2, varscan2
- KCNH4 | c.1812C>G p.L604= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99237748; called by muse, mutect2, varscan2
- KIF5B | c.1341G>A p.E447= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100192276; called by muse, mutect2, varscan2
- MACF1 | c.8148A>G p.K2716= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs552588079, COSV99246173; called by muse, mutect2, varscan2
- MSL3 | c.1210C>T p.L404= (on ENST00000312196 / NM_078629.4; = p.L238= on NM_006800.4) | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100385014; called by muse, mutect2, varscan2
- MYBBP1A | c.2760C>T p.A920= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs990273292, COSV99626719; called by muse, mutect2, varscan2
- MYO9B | c.849A>T p.G283= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV101261800; called by muse, mutect2, varscan2
- NUTM1 | c.1797C>A p.G599= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100149164; called by muse, mutect2, varscan2
- OR10H2 | c.207C>T p.S69= | Silent (SNP) | VAF 84/199 reads (42%) | catalogued as rs1448794833, COSV59945703; called by muse, mutect2, varscan2
- OR56A4 | c.618G>A p.R206= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV100417668; called by muse, mutect2, varscan2
- PAN2 | c.2421C>T p.V807= (on ENST00000425394 / NM_001127460.3; = p.V803= on NM_014871.5) | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as COSV99228442; called by muse, varscan2
- PCDH8 | c.1023C>T p.I341= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100131965; called by muse, mutect2, varscan2
- PCDHA12 | c.1155C>G p.V385= | Silent (SNP) | VAF 41/140 reads (29%) | catalogued as COSV100253126; called by muse, mutect2, varscan2
- PEDS1 | c.234C>G p.L78= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100502164; called by muse, mutect2, varscan2
- PRAM1 | c.795C>T p.D265= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV99725796; called by muse, mutect2, varscan2
- RELN | c.9705C>T p.C3235= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100634534; called by muse, mutect2, varscan2
- SAMM50 | c.1353G>A p.Q451= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV100601449; called by muse, mutect2
- SCN1A | c.2274A>G p.K758= (on ENST00000303395 / NM_001202435.3; = p.K747= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV100321486; called by muse, mutect2, varscan2
- SPSB3 | c.510G>A p.T170= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs769885735, COSV99236658; called by muse, mutect2, varscan2
- SPTBN2 | c.3720T>A p.S1240= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV100020191; called by muse, mutect2, varscan2
- TARBP2 | c.153C>G p.L51= (on ENST00000266987 / NM_134323.2; = p.L30= on NM_004178.4) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99908612; called by muse, mutect2, varscan2
- TEX15 | c.6852T>C p.N2284= (on ENST00000256246; = p.N2667= on NM_001350162.2) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99821907, COSV99821970; called by muse, mutect2, varscan2
- TPTE2 | c.888G>A p.E296= (on ENST00000400230 / NM_199254.2; = p.E219= on NM_130785.3) | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99690764; called by muse, mutect2, varscan2
- VPS37B | c.57C>T p.N19= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as rs1483269241, COSV57359769, COSV57360706; called by muse, mutect2, varscan2
- ZC4H2 | c.163C>T p.L55= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs149976823, COSV100565117; called by muse, mutect2, varscan2
- ZHX3 | c.1884G>A p.E628= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV100476034, COSV100476541; called by muse, mutect2, varscan2
- GBA3 | c.59-8328C>T | Intron (SNP) | VAF 54/184 reads (29%) | called by muse, mutect2, varscan2
- SON | c.6657+193G>A | Intron (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99279431; called by muse, mutect2, varscan2
- UPK3B | c.627-820G>A | Intron (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99991142; called by muse, mutect2, varscan2
